Surgical pathology report (de-identified scan), TCGA case TCGA-AP-A1E3, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site MSKCC, specimen TCGA-AP-A1E3-01A (Primary Tumor).

[page 1 of 4]
Specimens Submitted:

- 1: SP: Uterus, cervix bilateral fallopian tubes and ovaries, hysterectomy and bilateral salpingo-oophorectomy
- 2: SP: Pannus
- 3: SP: Right external iliac lymph nodes

DIAGNOSIS:

1. SP: Uterus, cervix bilateral fallopian tubes and ovaries, hysterectomy and bilateral salpingo-oophorectomy:

Tumor Type:

Adenocarcinoma, endometrioid type with a spindle cell component. - TSS cannot verify to spindle cell.

Architectural Grade (For Endometrioid Types only):

III (>50% solid growth)

See comment

Nuclear Grade (For Endometrioid Types only):

Grade 3

FIGO Grade (For Endometrioid Types only):

Grade 3

Myometrial Invasion:

(>50%)

Measures 34mm in maximum depth

Myometrium thickness measures 44mm in the area of maximal tumor

invasion

Endocervical Invasion:

Mucosa and stroma

Depth of cervical stromal invasion:

Measures 13mm

Cervical wall thickness measures 16mm in the area of maximum tumor

invasion

Lymphovascular invasion:

Identified

Endometrium:

Exhibits complex hyperplasia with atypia

Myometrium:

Exhibits multiple leiomyomata

Adnexa:

** Continued on next page **

ICD-O-3

carcinoma, endometrioid and spindle cell, NOS

8380/3

8032/3

code to highest

Site: Endometrium C54.1

bw
12/5/11

Criteria	TSS cannot verify spindle cell	Path	28
Diagnostic Discrepancy			
Site Discrepancy			
Joint Synchronous History			
Use is (circle):			

[page 2 of 4]
Right fallopian tube exhibits: no significant abnormality
Left fallopian tube exhibits: no significant abnormality
Bilateral ovaries reveal metastatic endometrioid endometrial

carcinoma.

Comment: The tumor displays at least two distinct morphologies: well differentiated endometrioid and high grade, solid, spindled, and transitional-cell like endometrioid adenocarcinoma.

NOTE: THERE IS METASTATIC CARCINOMA TO BOTH OVARIES, INCLUDING COLONIZATION OF BILATERAL ADENOFIBROMAS. ADDITIONAL IMMUNOSTAINS FOR MICROSATELLITE INSTABILITY TESTING ARE PENDING AND WILL BE REPORTED AS AN ADDENDUM.

2. "PANNUS", EXCISION:

- BENIGN SKIN AND FIBROADIPOSE TISSUE.

3. LYMPH NODES, RIGHT EXTERNAL ILIAC, EXCISION:

- METASTATIC ENDOMETRIOID ENDOMETRIAL CARCINOMA TO MATTED LYMPH NODE(S).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 3 of 4]
Procedures/Addenda:
Addendum

Addendum Diagnosis

Results of immunohistochemical staining for DNA mismatch repair proteins are as follows:

MLH1: Staining present in tumor

MSH2: Staining present in tumor

** Continued on next page **

[page 4 of 4]
TSS Name/#:

----- Page 5 of 5

MSH6: Staining present in tumor

PMS2: Staining present in tumor

Conclusion: Immunohistochemical staining for the tested DNA mismatch repair proteins is retained in the tumor.

** End of Report **

Source: NCI Genomic Data Commons file 98708051-7881-4c94-8a5e-2973728529b2 (TCGA-AP-A1E3.FDA2C217-5267-41CC-AC07-CBACFF8E7B8D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).